Gene-level copy-number profile of tumor specimen C3N-03885-03 from CPTAC case C3N-03885, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 32.7 years (11,945 days).
Specimen C3N-03885-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d131a56-5e73-45fa-bdc6-2d3046d48824.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03885-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,802 have no estimate.
https://portal.gdc.cancer.gov/files/bcffda28-04e6-48f0-a640-e2a0205c929c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 735; copy number 2: 4,817; copy number 3: 10,561; copy number 4: 17,217; copy number 5: 17,083; copy number 6: 4,255; copy number 7: 2,699; copy number 8: 772; copy number 9: 171; copy number 10: 196; copy number 11: 14; copy number 12: 45; copy number 13: 19; copy number 14: 73; copy number 15: 31; copy number 16: 1; copy number 17: 15; copy number 18: 50; copy number 19: 5; copy number 20: 4; copy number 25: 8.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:103,630,661–103,630,912, 1 gene: TUBBP11.
- chr6:81,813,286–81,814,157, 1 gene: LINC01526.
- chr7:86,775,081–86,776,022, 1 gene (within-gene range 0–3): AC005009.1.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr9:23,632,106–23,632,360, 1 gene: SUMO2P2.
- chr9:26,066,675–26,118,408, 1 gene: AL353753.1.
- chr9:41,233,755–42,499,134, 35 genes (within-gene range 0–2): MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:119,935,053–119,974,322, 2 genes: LINC01613, AL441989.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr12:100,852,331–100,859,262, 1 gene (within-gene range 0–4): AC138360.1.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–4): ERVK-28, AC112702.1, LINC00662, AC006504.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 621 genes in 70 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,020,120–1,116,361, 7 genes, copy number 9: AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223, C1orf159, AL390719.3.
- chr1:70,144,805–70,205,579, 2 genes, copy number 10 (within-gene range 4–10): LRRC40, RN7SL242P.
- chr1:102,876,467–103,108,872, 2 genes, copy number 13 (within-gene range 13–16): COL11A1, SOD2P1.
- chr1:105,433,994–106,865,316, 13 genes, copy number 9–18: CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1, AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661.
- chr1:108,746,674–109,047,482, 11 genes, copy number 10: STXBP3, AL591719.1, AKNAD1, SPATA42, GPSM2, CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5.
- chr1:112,177,234–114,780,685, 64 genes, copy number 11–18 (broad region; genes not listed).
- chr2:32,521,927–32,574,818, 6 genes, copy number 10 (within-gene range 10–11): AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4.
- chr2:55,172,547–55,451,099, 11 genes, copy number 9: CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P.
- chr2:89,851,791–91,781,169, 52 genes, copy number 10–13: IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr2:196,804,417–196,927,796, 3 genes, copy number 9: C2orf66, AC012486.1, PGAP1.
- chr3:61,742,455–62,875,416, 10 genes, copy number 10–20 (within-gene range 10–21): RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P.
- chr3:62,950,430–70,518,064, 77 genes, copy number 9–25 (broad region; genes not listed).
- chr3:70,954,708–71,754,229, 8 genes, copy number 9 (within-gene range 8–9): FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1.
- chr3:72,888,046–73,111,182, 8 genes, copy number 9: GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P.
- chr3:88,051,944–88,168,729, 5 genes, copy number 10: CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38.
- chr3:100,609,601–100,748,964, 4 genes, copy number 9–14: ADGRG7, AC069223.1, GMFBP1, TFG.
- chr3:153,067,278–153,377,562, 7 genes, copy number 9: HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2.
- chr3:172,750,682–172,831,229, 5 genes, copy number 9: ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1.
- chr3:179,323,031–179,452,419, 7 genes, copy number 9: ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1.
- chr5:50,603,229–50,846,519, 4 genes, copy number 9: AC112187.2, AC112187.1, AC112187.3, PARP8.
- chr5:88,189,633–88,439,090, 5 genes, copy number 19 (within-gene range 3–24): TMEM161B, RNA5SP187, RPS3AP22, AC091826.1, LINC02060.
- chr8:67,043,079–67,196,778, 4 genes, copy number 10 (within-gene range 8–10): COPS5, CSPP1, RNA5SP268, AC087359.1.
- chr8:98,943,595–99,013,743, 5 genes, copy number 10 (within-gene range 8–10): AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1.
- chr11:69,294,151–71,252,577, 45 genes, copy number 9: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:77,514,936–78,574,874, 34 genes, copy number 12–15 (within-gene range 3–15): CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2.
- chr12:22,409,237–22,618,868, 5 genes, copy number 10 (within-gene range 5–10): AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1.
- chr12:25,195,216–25,250,936, 4 genes, copy number 10: ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:68,610,855–68,671,901, 4 genes, copy number 10: RAP1B, RPL10P12, SNORA70G, ATP5PDP4.
- chr14:35,534,164–35,932,325, 9 genes, copy number 9 (within-gene range 4–9): INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2.
- chr14:44,876,874–45,200,890, 14 genes, copy number 9: AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM.
- chr14:106,821,174–106,879,812, 9 genes, copy number 9–11: IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:44,288,719–44,529,038, 7 genes, copy number 9–10 (within-gene range 7–10): GOLM2, GAPDHP43, AC090519.1, AC025043.1, CTDSPL2, HNRNPMP1, AC025430.1.
- chr15:56,630,181–56,734,086, 3 genes, copy number 10: ZNF280D, Y_RNA, AC090517.2.
- chr15:58,588,809–58,861,900, 12 genes, copy number 9 (within-gene range 7–9): ADAM10, HMGB1P51, AC091046.1, HSP90AB4P, RN7SKP95, AC091046.2, AC090515.6, AC090515.3, SNORD3P1, AC090515.2, MINDY2, AC090515.5.
- chr16:46,469,341–47,035,385, 22 genes, copy number 10: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2.
- chr20:11,608,436–11,926,609, 8 genes, copy number 10–11: AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1.
- chr20:13,008,972–13,996,443, 11 genes, copy number 12–14 (within-gene range 8–15): SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr21:7,744,962–9,129,752, 38 genes, copy number 9–14 (within-gene range 8–15): SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2.
- chr21:9,088,188–13,120,807, 33 genes, copy number 10–18: CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:40,346,500–40,410,289, 4 genes, copy number 10 (within-gene range 7–10): ADSL, AL022238.3, SGSM3, SGSM3-AS1.

Autosomal genes at a single copy (total copy number 1): 261. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
